Gene-level copy-number profile of tumor specimen ALCH-B0CW-TTP1-A from ALCHEMIST case ALCH-B0CW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.1 years (25,595 days).
Specimen ALCH-B0CW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1cf391fa-c653-4596-962a-d7af53bb7da4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/1192a296-448f-4641-90ac-05ad00072aa1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 11,930; copy number 2: 44,518; copy number 3: 1,549; copy number 4: 34; copy number 5: 104; copy number 6: 76; copy number 7: 94; copy number 9: 48; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,821,987–131,836,532, 3 genes: AC103564.3, AC103564.1, AC103564.2.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr8:43,493,937–46,028,892, 9 genes: AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr9:40,755,407–40,929,092, 5 genes: AL353626.3, RNU6-156P, AL353626.1, AL353626.2, MIR1299.
- chr10:14,986,942–14,987,515, 1 gene (within-gene range 0–2): OR7E110P.
- chr11:48,880,111–48,961,810, 6 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2.
- chr12:125,150,058–125,164,918, 2 genes: AC122688.2, AC122688.4.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.
- chr19:27,757,184–27,760,849, 1 gene (within-gene range 0–1): AC006504.1.
- chr20:34,955,810–35,002,437, 3 genes (within-gene range 0–2): MYH7B, MIR499A, MIR499B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 324 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,004,316–40,520,158, 103 genes, copy number 5 (broad region; genes not listed).
- chr10:43,900,874–46,030,714, 54 genes, copy number 5–10: LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, CXCL12, RPL9P21, AL356157.2, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4.
- chr12:220,621–990,053, 16 genes, copy number 7 (within-gene range 2–7): SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr12:1,529,891–6,820,799, 151 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
